Somatic mutation profile of tumor specimen TCGA-ET-A2N4-01A (aliquot TCGA-ET-A2N4-01A-12D-A19J-08) from TCGA case TCGA-ET-A2N4, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 53.9 years (19,671 days).
Specimen TCGA-ET-A2N4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77aca2f6-145a-41da-82a7-a18fee36be4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A2N4-10A (Blood Derived Normal), aliquot TCGA-ET-A2N4-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42853513-5439-41b4-85da-a93de941f706

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ATP1A2 | c.613T>A p.S205T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV63403579; called by muse, mutect2
- CGN | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 95/288 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.602); catalogued as rs750242369, COSV54969695; called by muse, mutect2, varscan2
- CYSLTR2 | c.776G>A p.C259Y | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56165728; called by muse, mutect2, varscan2
- FOXP3 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs782572328, CM066087, COSV66050927, COSV66051140; called by muse, mutect2
- GON4L | c.4336G>C p.V1446L | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV55192912; called by muse, mutect2
- HACL1 | c.835T>C p.F279L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58254367; called by muse, mutect2, varscan2
- LY9 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV54433737; called by muse, mutect2, varscan2
- PHLDB2 | c.3670T>A p.Y1224N (on ENST00000393925 / NM_001134439.2; = p.Y1181N on NM_145753.2) | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56325022; called by muse, mutect2, varscan2
- RP1 | c.5048C>A p.S1683Y | Missense Mutation (SNP) | VAF 23/265 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV55115852; called by muse, mutect2
- SFI1 | c.316A>G p.R106G | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66290595; called by muse, mutect2
- ACACB | c.1422G>T p.P474= | Silent (SNP) | VAF 180/426 reads (42%) | catalogued as COSV58133584; called by muse, mutect2, varscan2
- ADGRG3 | c.1044C>T p.F348= | Silent (SNP) | VAF 51/179 reads (28%) | catalogued as rs368898879; called by muse, mutect2, varscan2
- COL1A2 | c.3921G>A p.R1307= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV51957348; called by muse, mutect2, varscan2
- H3C13 | c.87C>T p.S29= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV100516079; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415027 G>C | 5'Flank (SNP) | VAF 17/37 reads (46%) | catalogued as COSV52567515; called by muse, mutect2, varscan2
